Somatic mutation profile of tumor specimen 0DP48A from CCDI case PBCBBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,406 days).
Specimen 0DP48A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3588dd77-cafe-4ef7-9333-9357b486177c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP46U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/007ec2cc-d85e-40af-93df-50dc4c7bbdb8

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPO | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 350/1696 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1035791118, CM032388; called by muse, mutect2, varscan2
- SLC25A2 | c.333C>T p.A111= | Silent (SNP) | VAF 38/1402 reads (3%) | catalogued as rs782238065, COSV99508175; called by muse, mutect2
- ZC3H7A | c.1791G>A p.P597= | Silent (SNP) | VAF 253/1510 reads (17%) | catalogued as rs1437625465, COSV63268658; called by muse, mutect2, varscan2
